Gene-level copy-number profile of tumor specimen TCGA-2G-AAII-01A from TCGA case TCGA-2G-AAII, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 37.7 years (13,761 days).
Specimen TCGA-2G-AAII-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4cedc2a0-b8c2-49d5-a62f-795970ba3eba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAII-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/41248e2b-df0e-48e8-8fb6-e57bd28b4a11

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 664; copy number 2: 31,691; copy number 3: 22,526; copy number 4: 3,982; copy number 5: 46.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:65,141,032–65,234,216, 1 gene, copy number 5: INTS4P1.
- chr12:42,687,195–46,373,778, 45 genes, copy number 5: LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2.

Autosomal genes at a single copy (total copy number 1): 152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
